Gene-level copy-number profile of tumor specimen TCGA-77-7463-01A from TCGA case TCGA-77-7463, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75.3 years (27,520 days).
Specimen TCGA-77-7463-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.8a30292c-f720-40b7-bd44-81b344071023.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7463-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e2ab9a9-738d-446d-b32d-c60c325c6d36

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 2: 7,987; copy number 3: 12,491; copy number 4: 12,583; copy number 5: 13,570; copy number 6: 6,274; copy number 7: 2,003; copy number 8: 216; copy number 9: 314; copy number 10: 2,662; copy number 11: 164; copy number 12: 561; copy number 13: 60; copy number 14: 710; copy number 21: 77; copy number 27: 4; copy number 28: 111.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-7463-01A-11D-2041-01): tumor purity 0.41, ploidy 4.5, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:857,124–858,091, 1 gene: AC090044.1.
- chr8:5,072,645–5,072,869, 1 gene: AC019176.1.
- chr9:123,843,036–123,843,686, 1 gene: PIGFP2.
- chr16:72,236,281–72,665,014, 1 gene (within-gene range 0–3): LINC01572.
- chr16:72,376,704–72,533,892, 2 genes: U6, AC004158.1.
- chr16:72,673,503–72,729,894, 2 genes: RNU7-90P, KRT18P18.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,687 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 14 (broad region; genes not listed).
- chr8:35,862,123–65,843,331, 479 genes, copy number 12–28 (broad region; genes not listed).
- chr8:71,828,167–72,118,393, 1 gene, copy number 12 (within-gene range 9–12): MSC-AS1.
- chr8:72,019,917–78,956,082, 97 genes, copy number 12 (broad region; genes not listed).
- chr8:85,172,077–88,328,025, 57 genes, copy number 12: AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16.
- chr8:142,212,080–142,403,182, 1 gene, copy number 11 (within-gene range 9–11): TSNARE1.
- chr8:142,403,652–145,066,685, 163 genes, copy number 11 (broad region; genes not listed).
- chr9:14,475–13,836,571, 175 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr9:16,409,503–16,870,843, 1 gene, copy number 27 (within-gene range 9–27): BNC2.
- chr9:16,625,676–16,775,845, 3 genes, copy number 27: AL450003.1, BNC2-AS1, LSM1P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
